MMRF case MMRF_1726 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bfe2f81d-7c4a-4d54-b87a-b47401d52c4f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 813 days (2.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.7 years (27,284 days); ISS stage: II; Days to last known disease status: 813 days (2.2 years); Days to last follow up: 813 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 135 days; Days to treatment end: 564 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 176 days; Days to treatment end: 564 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 564 days (1.5 years); Days to treatment end: 635 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 566 days (1.5 years); Days to treatment end: 635 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 664 days (1.8 years); Days to treatment end: 678 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 664 days (1.8 years); Days to treatment end: 693 days (1.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 813.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 3): M Protein 3.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.523 mg/dL; Immunoglobulin G 56.2 g/L; Immunoglobulin A 0.124 g/L; Immunoglobulin M 0.093 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 1.7 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.05 mmol/L; Albumin 28 g/L; Total Protein 9.2 g/dL; Glucose 6.22 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 85 (ECOG 3): M Protein 3.03 g/dL; Immunoglobulin G 32.8 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.98 mmol/L; Glucose 9.74 mmol/L.
- Day 190 (ECOG 3): M Protein 2.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.548 mg/dL; Immunoglobulin G 28 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 7.7 g/dL; Glucose 7.04 mmol/L.
- Day 323 (ECOG 3): M Protein 2.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.901 mg/dL; Immunoglobulin G 26.6 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.03 mmol/L; Albumin 30 g/L; Total Protein 7.6 g/dL; Glucose 9.02 mmol/L.
- Day 384 (ECOG 3): M Protein 2.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.492 mg/dL; Immunoglobulin G 29.8 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 29 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 496 (ECOG 3): M Protein 2.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 27 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.07 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.03 mmol/L; Albumin 29 g/L; Total Protein 7.8 g/dL; Glucose 5.72 mmol/L.
- Day 601 (ECOG 3): M Protein 2.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.606 mg/dL; Immunoglobulin G 27.5 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.39 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 1.93 mmol/L; Albumin 27 g/L; Total Protein 7.6 g/dL; Glucose 6.99 mmol/L.
- Day 704 (ECOG 3): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.774 mg/dL; Immunoglobulin G 29.9 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.87 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2 mmol/L; Albumin 27 g/L; Glucose 4.07 mmol/L.
- Day 783 (ECOG 3): M Protein 3.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 35.9 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.13 mmol/L; Albumin 25 g/L; Total Protein 8.6 g/dL; Glucose 8.69 mmol/L.

Other clinical attributes
- Day -2: Weight: 90 kg; Height: 177 cm.

Biospecimens (2 samples)
- Sample MMRF_1726_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1726_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
